Gene-level copy-number profile of tumor specimen C3L-02179-01 from CPTAC case C3L-02179, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 82.3 years (30,070 days).
Specimen C3L-02179-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4ffb502-c2bc-4cc7-b499-e04c1040a520.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02179-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/5de8de0b-0642-42a0-a77e-7d4206bfb9a0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 534; copy number 1: 9; copy number 2: 7,794; copy number 3: 5,236; copy number 4: 29,267; copy number 5: 1,703; copy number 6: 13,067; copy number 7: 1,282; copy number 8: 20.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:21,957,025–22,215,270, 31 genes (within-gene range 0–2): TOP3B, PRAMENP, IGLVI-70, IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
